Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A19M, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A19M-06A (Metastatic).

105-0-3

Melanoma, NOS 8720/3 12/15/10 *hr*

Site Code: Axilla, NOS C44.5

PATIENT HISTORY:

The patient has a history of melanoma left arm.
PRE-OP DIAGNOSIS: Melanoma left arm.
POST-OP DIAGNOSIS: Same.
PROCEDURE: Left axillary node dissection.

FINAL DIAGNOSIS:

LEFT AXILLARY LYMPH NODE DISSECTION -
METASTATIC MELANOMA IN NINE OUT OF FOURTEEN LYMPH NODES. FOCAL EXTRACAPSULAR SPREAD PRESENT.
LARGEST MASS IS 7.0 CM.

COMMENT:

Patient had prior negative sentinel node

Source: NCI Genomic Data Commons file 895b0bb5-3781-490d-a231-7b9e976c3b6a (TCGA-ER-A19M.9B318F5F-AA12-480C-91AA-757CEBEBD1A1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).